Gene-level copy-number profile of tumor specimen TCGA-AP-A0LF-01A from TCGA case TCGA-AP-A0LF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AP-A0LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.d022d05c-c054-496c-a0c8-b80d9116b38c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A0LF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d1283635-be29-4e30-b59a-d0f52fa75408

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,272; copy number 2: 14,469; copy number 3: 29,836; copy number 4: 4,556; copy number 5: 2,447; copy number 6: 2,081; copy number 7: 922; copy number 8: 2,276; copy number 9: 58; copy number 10: 363; copy number 11: 197; copy number 12: 24; copy number 13: 52; copy number 14: 34; copy number 15: 96; copy number 16: 61; copy number 26: 35; copy number 34: 20; copy number 38: 4; copy number 39: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A0LF-01A-11D-A120-01): tumor purity 0.38, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,149 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–176,447,919, 1,146 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr1:230,002,372–230,714,122, 11 genes, copy number 8: LINC01736, GALNT2, AL136988.2, AL136988.1, PGBD5, AL133516.1, LINC01737, AL158214.1, COG2, AL158214.2, AGT.
- chr1:233,904,676–235,328,219, 42 genes, copy number 9 (within-gene range 6–9): SLC35F3, RAC1P7, AL122008.3, AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753.
- chr1:243,124,428–243,255,348, 1 gene, copy number 10 (within-gene range 6–10): CEP170.
- chr1:243,164,638–244,451,909, 21 genes, copy number 10 (within-gene range 6–10): AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2.
- chr3:149,030,127–198,222,513, 887 genes, copy number 7–10 (broad region; genes not listed).
- chr4:164,725,310–164,726,706, 1 gene, copy number 10: CHORDC1P3.
- chr6:101,181,257–113,140,870, 185 genes, copy number 12–39 (broad region; genes not listed).
- chr6:114,822,994–118,454,992, 49 genes, copy number 13: AL590550.1, RNU6-475P, AL606845.1, LINC02534, FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3, AL050331.2, TSPYL4, DSE, AL050331.1, TSPYL1, Z84488.1, CBX3P9, KRT18P22, CALHM6-AS1, CALHM6, AL445224.1, TRAPPC3L, CALHM5, CALHM4, RWDD1, RSPH4A, ZUP1, KPNA5, FAM162B, GPRC6A, RFX6, RPS29P13, RNA5SP214, Z98880.1, VGLL2, ROS1, RN7SKP18, RN7SKP51, AL132671.2, RAP1BP3, AL132671.1, DCBLD1, RNU6-253P, GOPC, NEPNP, NUS1, SLC35F1, AL450405.1, AL589993.1.
- chr6:118,501,430–118,576,840, 3 genes, copy number 13 (within-gene range 4–13): BRD7P3, PLN, Z99496.1.
- chr6:120,015,179–124,825,640, 44 genes, copy number 7–9 (within-gene range 6–9): MIR3144, AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1.
- chr6:126,304,223–127,213,609, 1 gene, copy number 8 (within-gene range 6–8): AL356534.1.
- chr6:126,484,631–128,520,616, 27 genes, copy number 8 (within-gene range 4–8): MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1.
- chr7:56,101,573–57,245,931, 74 genes, copy number 8–10 (broad region; genes not listed).
- chr7:115,061,537–127,652,012, 164 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr7:135,183,839–141,480,380, 116 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:39,934,614–43,674,591, 92 genes, copy number 14–16 (within-gene range 2–16) (broad region; genes not listed).
- chr8:123,851,987–125,367,120, 34 genes, copy number 7 (within-gene range 3–7): FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P.
- chr8:137,105,352–137,645,564, 3 genes, copy number 8 (within-gene range 3–8): RNU6-144P, ZYXP1, AC105213.1.
- chr10:44,712–2,502,200, 39 genes, copy number 10: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2.
- chr12:16,347,142–16,609,259, 1 gene, copy number 14 (within-gene range 3–14): MGST1.
- chr12:16,420,653–16,514,371, 2 genes, copy number 14 (within-gene range 3–14): AC007528.1, AC007552.1.
- chr12:16,567,411–16,573,940, 1 gene, copy number 12: AC007552.2.
- chr13:97,168,751–110,136,906, 179 genes, copy number 7 (broad region; genes not listed).
- chr14:50,418,501–51,257,655, 26 genes, copy number 7 (within-gene range 4–7): MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA.
- chr15:33,105,758–36,252,257, 67 genes, copy number 11 (broad region; genes not listed).
- chr19:7,728,958–24,129,968, 881 genes, copy number 8 (broad region; genes not listed).
- chr21:18,269,116–19,345,312, 14 genes, copy number 8: TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P.
- chr21:30,281,309–30,762,882, 38 genes, copy number 7: KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1, KRTAP19-1, KRTAP19-2, KRTAP19-3, KRTAP19-4, KRTAP19-5, KRTAP19-9P, KRTAP19-10P, AP000567.1, KRTAP19-11P, KRTAP19-6, KRTAP19-7, KRTAP22-2, KRTAP6-3, KRTAP6-2, KRTAP22-1, KRTAP6-1, KRTAP20-1, KRTAP20-4, KRTAP20-2, KRTAP20-3, KRTAP21-3, KRTAP21-4P, KRTAP21-2, KRTAP21-1, AP000244.1.

Autosomal genes at a single copy (total copy number 1): 694. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
